Gene-level copy-number profile of tumor specimen TCGA-TQ-A7RV-02A from TCGA case TCGA-TQ-A7RV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.8 years (10,167 days).
Specimen TCGA-TQ-A7RV-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2fa5d9bc-8462-4934-b7a7-ae6bd27f57d6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A7RV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/116a3eec-0901-41ae-80ae-e51705b4befc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,400; copy number 1: 1,754; copy number 2: 52,866; copy number 3: 3,152; copy number 4: 12; copy number 5: 38; copy number 6: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TQ-A7RV-02A-11D-A36N-01): tumor purity 0.53, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:168,598,240–168,598,757, 1 gene: BTF3L4P4.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:20,532,552–20,533,339, 1 gene: AL163193.1.
- chr9:33,218,365–33,248,567, 1 gene (within-gene range 0–2): SPINK4.
- chr11:58,387,583–58,388,486, 1 gene: OR5B15P.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.
- chr17:3,721,628–3,730,493, 3 genes: AC116914.2, HASPIN, AC116914.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,744,299–152,762,052, 2 genes, copy number 5: LCEP1, KPRP.
- chr8:93,857,807–93,974,776, 6 genes, copy number 5 (within-gene range 3–5): PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1.
- chr8:104,590,733–105,804,539, 1 gene, copy number 6 (within-gene range 3–6): ZFPM2.
- chr8:105,142,860–109,691,791, 47 genes, copy number 6 (within-gene range 3–6): AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1.
- chr8:144,698,614–145,066,685, 21 genes, copy number 5: AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr10:22,345,445–22,787,499, 7 genes, copy number 5: SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P.
- chr11:102,691,487–102,727,050, 2 genes, copy number 5 (within-gene range 3–5): MMP27, MMP8.

Autosomal genes at a single copy (total copy number 1): 1,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
